TARGET case TARGET-10-CAAABC — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/16b11635-0019-5e66-a011-0d99508f8858

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary.

Biospecimens (17 samples)
- Sample TARGET-10-CAAABC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-CAAABC-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-CAAABC-60.10B, TARGET-10-CAAABC-60.12B, TARGET-10-CAAABC-60.16B, TARGET-10-CAAABC-60.18B, TARGET-10-CAAABC-60.1A, TARGET-10-CAAABC-60.1B, TARGET-10-CAAABC-60.1C, TARGET-10-CAAABC-60.2A, TARGET-10-CAAABC-60.3A, TARGET-10-CAAABC-60.3C, TARGET-10-CAAABC-60.4A, TARGET-10-CAAABC-60.4B, TARGET-10-CAAABC-60.5A, TARGET-10-CAAABC-60.6A, TARGET-10-CAAABC-60.7B (15 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Cell of Origin: T Cell ALL
